Somatic mutation profile of tumor specimen TARGET-15-SJMPAL042941-09A.2 (aliquot TARGET-15-SJMPAL042941-09A.2-01D) from TARGET case TARGET-15-SJMPAL042941, project TARGET-ALL-P3 (Acute Lymphoblastic Leukemia - Phase III). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 0.4 years (140 days).
Specimen TARGET-15-SJMPAL042941-09A.2: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 98418859-07fa-4820-ae15-cebc71f2b766.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-15-SJMPAL042941-14A (Bone Marrow Normal), aliquot TARGET-15-SJMPAL042941-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/13197d2c-02dc-4193-9c4b-3a067b46cd23

The open-access MAF lists 3 somatic variants for this specimen: 2 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 2, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KLRC2 | c.585G>T p.K195N | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- RYR2 | c.431C>A p.A144D | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.889); called by muse, mutect2
- MUC12 | c.13551A>C p.T4517= (on ENST00000379442; = p.T4374= on NM_001164462.1) | Silent (SNP) | VAF 20/120 reads (17%) | catalogued as rs577319577; called by mutect2, varscan2
